Gene-level copy-number profile of tumor specimen TCGA-AA-3685-01A from TCGA case TCGA-AA-3685, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 69.8 years (25,506 days).
Specimen TCGA-AA-3685-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d8b1a067-f891-486f-befe-415a9ec4d6e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3685-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ffae3639-e03a-4399-8f54-78d46d9e4a3a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 869; copy number 2: 31,320; copy number 3: 20,200; copy number 4: 3,367; copy number 5: 3,043; copy number 6: 896; copy number 7: 63; copy number 8: 40; copy number 10: 12; copy number 11: 5; copy number 17: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-3685-01A-02D-0903-01): tumor purity 0.6, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,705,558, 2 genes: AC007223.1, AC007012.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,061 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–109,999,624, 2,047 genes, copy number 5 (broad region; genes not listed).
- chr7:110,662,644–111,562,517, 1 gene, copy number 5 (within-gene range 3–5): IMMP2L.
- chr7:111,091,006–159,233,377, 962 genes, copy number 5 (broad region; genes not listed).
- chr11:54,591,480–55,607,645, 33 genes, copy number 5: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4, AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16, OR4A15, OR4A9P, OR4X7P, OR4A10P, OR4A17P, OR4A13P, OR4A50P, OR4A21P, OR4C1P, OR4C14P, OR4C15, OR4C16, OR4C11.
- chr20:3,471,018–4,249,287, 25 genes, copy number 7 (within-gene range 4–7): ATRN, GFRA4, ADAM33, SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3, RPL21P2, AL356414.1, SMOX, LINC01433, ADRA1D.
- chr20:5,292,388–5,503,189, 5 genes, copy number 11 (within-gene range 4–11): UBE2D3P1, PROKR2, AL121757.2, RNA5-8SP7, AL121757.3.
- chr20:7,069,614–13,638,932, 78 genes, copy number 7–8 (broad region; genes not listed).
- chr20:13,995,369–16,053,197, 1 gene, copy number 10 (within-gene range 3–17): MACROD2.
- chr20:14,322,985–15,619,819, 13 genes, copy number 10–17: FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.
- chr20:30,294,550–64,313,132, 896 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 869. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
